Somatic mutation profile of tumor specimen CDDP-ABJP-TTP1-B (aliquot CDDP-ABJP-TTP1-B-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJP, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71 years.
Specimen CDDP-ABJP-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbb14c54-f510-4825-987f-94675c329856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJP-NB1-A (Blood Derived Normal), aliquot CDDP-ABJP-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/357e5b6f-ab3a-4b06-b288-31845185a8f1

The open-access MAF lists 537 somatic variants for this specimen: 348 protein-altering or splice-affecting, 125 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 300, Silent 125, Nonsense Mutation 25, Intron 24, RNA 14, 3'UTR 10, 5'Flank 9, Splice Site 8, Frame Shift Del 6, 5'UTR 5, Splice Region 5, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 60/182 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 94/200 reads (47%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6367C>G p.L2123V | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV70035072; called by muse, mutect2, varscan2
- ADAM2 | c.844T>G p.F282V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV55864951; called by muse, mutect2, varscan2
- ADAMTS14 | c.2395A>T p.S799C | Missense Mutation (SNP) | VAF 95/179 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs755709221; called by muse, mutect2, varscan2
- ADAMTS4 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63490631; called by muse, mutect2, varscan2
- AHNAK | c.8702A>T p.K2901M | Missense Mutation (SNP) | VAF 148/309 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57221275; called by muse, mutect2, varscan2
- AKT2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 121/359 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs1485745630, COSV60909229, COSV60909859; called by muse, mutect2, varscan2
- ALDH1A3 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs745641363, COSV60902467; called by muse, mutect2, varscan2
- AMPH | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV57748906; called by muse, mutect2, varscan2
- ANGPTL4 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56845146; called by muse, mutect2, varscan2
- ANKRD17 | c.2505G>T p.L835F | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV58223826; called by muse, mutect2, varscan2
- ANKRD17 | c.2504T>C p.L835S | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); catalogued as COSV58223831; called by muse, mutect2, varscan2
- ANKRD31 | c.5482T>C p.S1828P | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV57161816; called by muse, varscan2
- APOBEC3H | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV62378914, COSV62378918; called by muse, mutect2, varscan2
- AQP9 | c.809A>C p.H270P | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54969588; called by muse, mutect2, varscan2
- ARG2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV53620254; called by muse, mutect2, varscan2
- ARID1A | c.6634C>T p.Q2212* | Nonsense Mutation (SNP) | VAF 94/181 reads (52%) | catalogued as COSV61382589; called by muse, mutect2, varscan2
- ARL13B | c.605A>G p.Q202R (on ENST00000394222 / NM_001174150.2; = p.Q95R on NM_144996.4) | Missense Mutation (SNP) | VAF 114/492 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV57399703; called by muse, mutect2, varscan2
- ARL13B | c.665G>A p.R222Q (on ENST00000394222 / NM_001174150.2; = p.R115Q on NM_144996.4) | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1478163991, COSV100115133; called by muse, mutect2
- ASAH2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 12/132 reads (9%) | catalogued as COSV61484553; called by muse, mutect2
- ASB2 | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV60113249; called by muse, mutect2, varscan2
- ASPM | c.1769T>A p.I590N | Missense Mutation (SNP) | VAF 219/680 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54133448; called by muse, mutect2, varscan2
- ASPM | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1379765257, COSV54133456; called by muse, mutect2, varscan2
- ATF7IP | c.2392C>G p.L798V | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV53773763; called by muse, mutect2, varscan2
- ATP2C1 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60759048; called by muse, mutect2, varscan2
- ATP7B | c.2795C>G p.S932* | Nonsense Mutation (SNP) | VAF 27/479 reads (6%) | catalogued as CM040680; called by muse, mutect2
- BBS4 | c.342G>T p.L114F | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51438952; called by muse, mutect2, varscan2
- BCL2L1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 111/370 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV56968501; called by muse, mutect2, varscan2
- BCOR | c.4432G>A p.V1478M (on ENST00000378444 / NM_001123385.2; = p.V1444M on NM_017745.6) | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs777585092, COSV60712299; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1873C>A p.Q625K | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs762256976, COSV63245954; called by muse, mutect2, varscan2
- C20orf202 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV68763944; called by muse, mutect2, varscan2
- C2orf16 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV68646509; called by muse, mutect2, varscan2
- CALM3 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52194679; called by muse, mutect2, varscan2
- CASZ1 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 234/423 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59738404; called by muse, mutect2, varscan2
- CDH10 | c.1940A>T p.K647I | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV52587884; called by muse, varscan2
- CDH18 | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.836); catalogued as COSV56960606; called by muse, mutect2
- CDHR5 | c.1380G>C p.E460D (on ENST00000358353 / NM_001171968.2; = p.E466D on NM_021924.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV57644678; called by muse, mutect2, varscan2
- CDON | c.3598G>T p.D1200Y | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV54999986; called by muse, mutect2, varscan2
- CEP104 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV65518206; called by muse, mutect2, varscan2
- CEP78 | c.1221C>G p.I407M (on ENST00000424347 / NM_001349840.2; = p.I408M on NM_032171.3) | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV52848824; called by muse, mutect2, varscan2
- CFAP44 | c.2399A>T p.Y800F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55613473; called by muse, mutect2, varscan2
- CLASP1 | c.2342C>G p.P781R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV55330165; called by muse, mutect2, varscan2
- CLCA4 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV55366940, COSV55369585; called by muse, mutect2, varscan2
- CLIP4 | c.1142A>T p.H381L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as COSV60750543; called by muse, mutect2, varscan2
- CNTNAP1 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 50/164 reads (30%) | catalogued as COSV52851929, COSV52852243; called by muse, varscan2
- CNTNAP2 | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62216174; called by muse, mutect2, varscan2
- COL4A4 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61634125; called by mutect2, varscan2
- COL5A1 | c.5158G>T p.G1720C | Missense Mutation (SNP) | VAF 227/407 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65671711; called by muse, mutect2, varscan2
- COL6A6 | c.1760A>T p.E587V | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV62017733, COSV62030387; called by muse, mutect2, varscan2
- CPN2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 82/862 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60470977; called by muse, mutect2
- CRB1 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as rs746307301, COSV66328535, COSV66331669; called by muse, mutect2, varscan2
- CSMD3 | c.4111C>G p.H1371D (on ENST00000297405 / NM_001363185.1; = p.H1267D on NM_052900.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52167596, COSV52240601; called by muse, mutect2, varscan2
- CTC1 | c.371T>C p.L124S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV59854161; called by muse, mutect2, varscan2
- CXXC1 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV53275710, COSV99497409; called by muse, mutect2, varscan2
- CXorf66 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs1569496554, COSV100983945; called by muse, mutect2, varscan2
- CYB5R3 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1478738158; called by muse, mutect2
- DCHS1 | c.7407C>A p.H2469Q | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV54998785; called by muse, mutect2, varscan2
- DHRS7 | c.940A>C p.K314Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV53666876; called by muse, mutect2, varscan2
- DNAH3 | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs376419884; called by muse, mutect2, varscan2
- DNAH7 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs375823545; called by muse, varscan2
- DNAI1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 87/727 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755122846, COSV54280503; called by muse, mutect2, varscan2
- DPH6 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766114531, COSV56616545; called by muse, mutect2, varscan2
- DYTN | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV71752523; called by muse, mutect2, varscan2
- EFCC1 | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs767960796, COSV71401969; called by muse, mutect2, varscan2
- EML4 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100580553; called by muse, mutect2
- EML5 | c.2695G>A p.V899M | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV61348481; called by muse, mutect2, varscan2
- EPDR1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.371); catalogued as rs745401873; called by muse, mutect2
- FAM114A1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as rs372301008; called by muse, mutect2, varscan2
- FAM135B | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV50531217; called by muse, mutect2, varscan2
- FCER1G | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV57154295; called by muse, mutect2, varscan2
- FCHO1 | c.1762C>G p.P588A | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV53183592; called by muse, mutect2, varscan2
- FER1L6 | c.5297T>C p.V1766A | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183427684; called by muse, mutect2, varscan2
- FGF14 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 127/382 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.079); catalogued as COSV65949090; called by muse, mutect2, varscan2
- FHOD3 | c.662C>G p.S221W | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57176146; called by muse, mutect2, varscan2
- FMNL2 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV56499031; called by muse, mutect2, varscan2
- FOXO1 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 160/289 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV65427547; called by muse, mutect2, varscan2
- FOXO4 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58575738; called by muse, mutect2, varscan2
- FSTL5 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs751094663, COSV60209836; called by muse, mutect2
- GBF1 | c.1787A>C p.K596T (on ENST00000369983 / NM_001377137.1; = p.K595T on NM_004193.3) | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV64146853; called by muse, mutect2, varscan2
- GK3P | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as COSV56974906, COSV56981392; called by muse, mutect2, varscan2
- HIRIP3 | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54230994; called by muse, mutect2, varscan2
- IFT74 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 114/313 reads (36%) | catalogued as rs751583919, COSV66287756; called by muse, mutect2, varscan2
- IGHV3-23 | c.160A>C p.S54R | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs782264567; called by muse, mutect2
- ITGA4 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52001850, COSV52003303; called by muse, mutect2, varscan2
- ITPKB | c.2297G>C p.R766P | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55265478, COSV55265679; called by muse, mutect2, varscan2
- KALRN | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53772291; called by muse, mutect2, varscan2
- KANK4 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV58093353; called by muse, mutect2, varscan2
- KIF16B | c.2990G>C p.R997T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV61709470; called by muse, mutect2
- KLK13 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs776990347, COSV50067343, COSV50067386; called by muse, mutect2, varscan2
- LAMC3 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 404/946 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63093478; called by muse, mutect2, varscan2
- LHPP | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64330240; called by muse, mutect2, varscan2
- LILRA1 | c.71-2A>G p.X24_splice | Splice Site (SNP) | VAF 30/204 reads (15%) | catalogued as rs1241126166, COSV52185794; called by muse, mutect2
- LILRB5 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as rs1385790349, COSV60256356, COSV60260489; called by muse, mutect2
- LIMS1 | c.156+3G>A | Splice Region (SNP) | VAF 71/863 reads (8%) | catalogued as rs752933560; called by muse, mutect2
- LINGO1 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62437676; called by muse, mutect2, varscan2
- LNPK | c.1083T>G p.D361E | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV55825076; called by muse, mutect2, varscan2
- LRFN2 | c.1544C>A p.T515N | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57830660; called by muse, mutect2, varscan2
- LRFN2 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs754220525, COSV57830673; called by muse, mutect2, varscan2
- LRP11 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | catalogued as rs11278; called by muse, mutect2, varscan2
- LRPPRC | c.4108G>T p.V1370F | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs200059839, COSV53240484; called by muse, mutect2, varscan2
- LRRC45 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as COSV60712194; called by muse, mutect2, varscan2
- LRRC45 | c.971A>T p.E324V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1374302863, COSV60712204; called by muse, mutect2, varscan2
- LY75 | c.2170G>A p.G724R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109308; called by muse, mutect2, varscan2
- LY86 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165611551, COSV57913033; called by muse, varscan2
- MAGEC3 | c.1010C>A p.S337* | Nonsense Mutation (SNP) | VAF 119/217 reads (55%) | catalogued as COSV99036287; called by muse, mutect2, varscan2
- MAGEL2 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs372275206; called by muse, mutect2, varscan2
- MAP2 | c.4368T>G p.D1456E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.893); catalogued as COSV52298645; called by muse, varscan2
- MAP3K10 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1176751508, COSV53423649, COSV99454201; called by muse, mutect2, varscan2
- MBD3L2B | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 136/596 reads (23%) | catalogued as COSV61827421; called by muse, mutect2, varscan2
- MCM5 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV53347178; called by muse, mutect2, varscan2
- MDM1 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 89/137 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776183237, COSV57447586; called by muse, mutect2, varscan2
- MEFV | c.397C>G p.R133G | Missense Mutation (SNP) | VAF 161/302 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); catalogued as COSV54824487, COSV54825840; called by muse, mutect2, varscan2
- MEIS2 | c.727C>A p.Q243K (on ENST00000561208 / NM_170675.5; = p.Q230K on NM_002399.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV54939939; called by muse, mutect2, varscan2
- MPP4 | c.1751C>G p.A584G | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs1476409592, COSV53805627; called by muse, mutect2, varscan2
- MUC22 | c.4261G>A p.A1421T | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (0.69); catalogued as COSV73736447; called by muse, mutect2, varscan2
- MUC5B | c.12949A>T p.K4317* | Nonsense Mutation (SNP) | VAF 147/428 reads (34%) | catalogued as COSV71593996; called by muse, mutect2, varscan2
- NBN | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 62/146 reads (42%) | catalogued as COSV55374696; called by muse, mutect2, varscan2
- NCOR2 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1183978827; called by muse, mutect2, varscan2
- NDUFAF6 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54409617; called by muse, mutect2, varscan2
- NECAB2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs769976032, COSV59422022; called by muse, mutect2, varscan2
- NECTIN4 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 234/825 reads (28%) | catalogued as COSV63513306; called by muse, mutect2, varscan2
- NID2 | c.3229C>A p.Q1077K | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV53499386; called by muse, mutect2, varscan2
- NME8 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV52252806; called by muse, mutect2, varscan2
- NOS3 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs756713322, COSV52492387; called by muse, mutect2
- NTSR1 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs774996029, COSV65138016, COSV65139052; called by muse, mutect2, varscan2
- OPHN1 | c.574A>C p.K192Q | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62784191; called by muse, mutect2, varscan2
- OR10J3 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.71); catalogued as COSV59954498, COSV59954984, COSV59955013; called by muse, mutect2, varscan2
- OR2T33 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 111/437 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs1433685893, COSV58815909; called by muse, varscan2
- OR2V2 | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 120/239 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60316002; called by muse, mutect2, varscan2
- OR4C12 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV58859898; called by muse, mutect2, varscan2
- OR51T1 | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59025658; called by muse, mutect2
- OR52N2 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs189995648, COSV57677260; called by muse, mutect2, varscan2
- OR52W1 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs141469388, COSV60951273; called by muse, mutect2, varscan2
- OR5D13 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs763757727, COSV62334485, COSV62334932; called by muse, mutect2, varscan2
- OSBPL6 | c.2206A>G p.I736V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.628); catalogued as COSV51923123; called by muse, mutect2, varscan2
- P2RY14 | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56386603; called by muse, mutect2, varscan2
- PACRGL | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV54843771; called by muse, mutect2, varscan2
- PANX3 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52512942; called by muse, mutect2, varscan2
- PAPPA | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 153/264 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60287483; called by muse, mutect2, varscan2
- PCDH11X | c.2060C>A p.P687Q | Missense Mutation (SNP) | VAF 161/256 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53456679, COSV53464294; called by muse, mutect2, varscan2
- PCDHB16 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.036); catalogued as COSV104381877; called by muse, mutect2
- PDE1C | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58513464, COSV58525821; called by muse, varscan2
- PEG3 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1364840436, COSV55639517; called by muse, mutect2, varscan2
- PGK2 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV59164597; called by muse, mutect2, varscan2
- PHF24 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54275504; called by muse, mutect2, varscan2
- PMS2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 69/509 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751799116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMA5 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs782191927, COSV62625888; called by muse, mutect2, varscan2
- PODXL2 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 127/443 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61065919; called by muse, mutect2, varscan2
- POLD1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.218); catalogued as COSV54531783; called by muse, mutect2, varscan2
- POLE | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 140/251 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57684842; called by muse, mutect2, varscan2
- POLR1F | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55998955; called by muse, mutect2, varscan2
- POM121L2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV66276703, COSV66277148; called by muse, mutect2, varscan2
- POTEH | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 50/816 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as COSV100624763, COSV58880937; called by muse, mutect2
- PRAME | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1239996626, COSV67162004; called by muse, mutect2, varscan2
- PSKH2 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV52611473; called by muse, mutect2, varscan2
- PXDNL | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV62492922; called by muse, mutect2, varscan2
- RAB28 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV56538452, COSV56540840; called by muse, mutect2, varscan2
- RAB36 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs377124540; called by muse, mutect2, varscan2
- RANBP3 | c.757G>C p.D253H (on ENST00000340578 / NM_007322.3; = p.D248H on NM_003624.3) | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV50383464; called by muse, mutect2, varscan2
- RASIP1 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 154/446 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV55806448; called by muse, mutect2, varscan2
- RIC1 | c.3397C>A p.P1133T | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV52612128; called by muse, mutect2, varscan2
- RIN3 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1469035301, COSV53651911; called by muse, mutect2, varscan2
- RNF183 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as rs202129303; called by muse, mutect2, varscan2
- RUNX3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV58244788, COSV58244851; called by muse, mutect2, varscan2
- RUSF1 | c.773+7C>T | Splice Region (SNP) | VAF 62/261 reads (24%) | catalogued as rs772359749; called by muse, mutect2, varscan2
- RYR2 | c.1813G>T p.G605* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV63697775; called by muse, varscan2
- SCG3 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55022053; called by muse, mutect2, varscan2
- SCG3 | c.937A>T p.M313L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV55022060; called by muse, mutect2, varscan2
- SCN2A | c.5068G>A p.G1690R | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51855125; called by muse, mutect2
- SCN7A | c.2402C>A p.T801N | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.197); catalogued as COSV69271156, COSV69273023; called by muse, mutect2, varscan2
- SCNN1B | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56307259; called by muse, mutect2, varscan2
- SCYL3 | c.1705T>C p.S569P (on ENST00000367770; = p.S515P on NM_020423.7) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53680635; called by muse, mutect2, varscan2
- SDCBP2 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60590045; called by muse, mutect2, varscan2
- SEC11A | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51611956; called by muse, mutect2, varscan2
- SEMA5A | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV66799242; called by muse, mutect2, varscan2
- SHANK1 | c.4801C>G p.P1601A | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.287); catalogued as COSV53255964, COSV53262967; called by muse, mutect2, varscan2
- SKI | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 137/266 reads (52%) | catalogued as COSV66013995; called by muse, mutect2, varscan2
- SLC15A4 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 93/132 reads (70%) | catalogued as COSV57162514; called by muse, mutect2, varscan2
- SLC17A7 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 128/430 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV55548631; called by muse, mutect2, varscan2
- SLC22A16 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV57931757; called by muse, mutect2, varscan2
- SLC43A1 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs747650715, COSV53560040; called by muse, mutect2, varscan2
- SLC6A2 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs565379784, COSV54919555; called by muse, mutect2, varscan2
- SMC2 | c.3130A>G p.I1044V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761959232, COSV53960798; called by muse, mutect2, varscan2
- SMTN | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1416947889, COSV60780378; called by muse, mutect2, varscan2
- SNX20 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56058075; called by muse, mutect2, varscan2
- SON | c.4234G>C p.A1412P | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV51664324; called by muse, mutect2, varscan2
- SOS2 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV53570216; called by muse, varscan2
- SOX2 | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 222/1190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1249553271, CM099928, COSV57622262; called by muse, mutect2, varscan2
- SPA17 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55015044, COSV55015594; called by muse, mutect2, varscan2
- SPAG6 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV57621929; called by muse, mutect2, varscan2
- SPATA32 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 232/729 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV59304326; called by muse, mutect2, varscan2
- SPATS2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1463648348, COSV100423456; called by muse, mutect2
- ST8SIA6 | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV66469928; called by muse, mutect2, varscan2
- STARD13 | c.463C>A p.R155S (on ENST00000336934 / NM_001243476.3; = p.R37S on NM_052851.3) | Missense Mutation (SNP) | VAF 131/219 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55233514, COSV55237095; called by muse, mutect2, varscan2
- STAT4 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV61831002; called by muse, mutect2, varscan2
- SYNJ1 | c.4450C>A p.Q1484K | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV59151858; called by muse, mutect2, varscan2
- TAAR2 | c.857C>T p.P286L (on ENST00000367931 / NM_001033080.1; = p.P241L on NM_014626.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51579503; called by muse, mutect2, varscan2
- TBC1D8B | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52177688, COSV52180936; called by muse, mutect2, varscan2
- TENM4 | c.6082A>C p.T2028P | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53646403; called by muse, mutect2, varscan2
- TLE4 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 175/411 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs778270483, COSV54635764; called by muse, mutect2, varscan2
- TMEM155 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV61795278; called by muse, mutect2, varscan2
- TNFRSF6B | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53928291; called by mutect2, varscan2
- TOMM7 | c.152+1G>A p.X51_splice | Splice Site (SNP) | VAF 88/178 reads (49%) | catalogued as rs111732724; called by muse, mutect2
- TOR1AIP2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62626556; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs199665200; called by muse, mutect2, varscan2
- TRGV9 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as rs767279739; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV61457216; called by muse, mutect2, varscan2
- TSNARE1 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV56179274; called by muse, mutect2, varscan2
- TTN | c.99158C>T p.S33053L (on ENST00000591111; = p.S25629L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | PolyPhen probably damaging (0.996); catalogued as COSV59926672; called by muse, mutect2, varscan2
- TTN | c.92689C>A p.R30897S (on ENST00000591111; = p.R23473S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV60183449; called by muse, mutect2, varscan2
- UBASH3A | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 173/503 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52314080; called by muse, mutect2, varscan2
- UBE4A | c.1561G>A p.G521R (on ENST00000252108 / NM_001204077.2; = p.G528R on NM_004788.4) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52805379; called by muse, varscan2
- USP38 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV61026675; called by muse, mutect2, varscan2
- VIL1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.597); catalogued as rs774180643; called by muse, mutect2, varscan2
- VN1R2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59038935; called by muse, mutect2, varscan2
- WAC | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as COSV61566892; called by muse, mutect2, varscan2
- WDR25 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 131/249 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765439153, COSV58935760; called by muse, mutect2, varscan2
- WNT9A | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs148384382; called by muse, mutect2, varscan2
- ZCCHC18 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 116/164 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV62459791; called by muse, mutect2, varscan2
- ZFAT | c.2422T>A p.S808T | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV64741858; called by muse, mutect2, varscan2
- ZFP69 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65528903; called by muse, mutect2
- ZHX2 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as COSV58714840; called by muse, mutect2, varscan2
- ZNF180 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261090946; called by muse, mutect2
- ZNF292 | c.4412C>G p.P1471R | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60542532; called by muse, mutect2, varscan2
- ZNF45 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as rs756086970, COSV54193880; called by muse, mutect2, varscan2
- ZNF492 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV101514065; called by muse, mutect2, varscan2
- ZNF518B | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs752982266, COSV58721796; called by muse, mutect2, varscan2
- ZNF568 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771053654, COSV61740892, COSV61741839; called by muse, mutect2, varscan2
- ZNF582 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV56733037; called by muse, mutect2, varscan2
- ZNF665 | c.1715T>C p.V572A (on ENST00000600412; = p.V637A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.192); catalogued as rs763659028, COSV101128662; called by muse, mutect2, varscan2
- ZNF718 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as rs1553814793; called by muse, mutect2, varscan2
- ZNF823 | c.1402G>C p.E468Q (on ENST00000341191 / NM_001297610.2; = p.E424Q on NM_017507.2) | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57875484; called by muse, mutect2
- ZNF827 | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV65229356; called by muse, varscan2
- ZPLD1 | c.20T>A p.L7Q (on ENST00000466937 / NM_001329788.1; = p.L23Q on NM_175056.2) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60354801; called by muse, mutect2, varscan2
- ABCC1 | c.2372T>A p.F791Y | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ABI2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRD2 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 71/606 reads (12%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, varscan2
- AHCTF1 | c.2569G>C p.D857H (on ENST00000366508; = p.D831H on NM_015446.5) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AKAP10 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALG1L2 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG12 | c.80del p.P27Qfs*33 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by mutect2, pindel, varscan2
- ATG2A | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- BTBD17 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2
- C10orf71 | c.3318G>T p.R1106S | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- C4orf17 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA2D2 | c.2936+7C>G | Splice Region (SNP) | VAF 103/183 reads (56%) | called by muse, mutect2, varscan2
- CASR | c.1929del p.L644Sfs*20 (on ENST00000490131; = p.L721Sfs*20 on NM_000388.4) | Frame Shift Del (DEL) | VAF 41/211 reads (19%) | called by mutect2, pindel, varscan2
- CCDC63 | c.1481C>A p.P494Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CCDC85A | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- CEP192 | c.1759C>G p.Q587E | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2
- CTNND2 | c.2583C>A p.D861E | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CXCL17 | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYRIB | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCHS1 | c.3672A>G p.I1224M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); called by muse, mutect2
- DENND6A | c.818+6G>T | Splice Region (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- DGKD | c.2285G>C p.C762S (on ENST00000264057 / NM_152879.3; = p.C718S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DMD | c.10805C>T p.A3602V | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- DMD | c.10804G>C p.A3602P | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- EFEMP1 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EIF2AK3 | c.1165+1G>T p.X389_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- EIF2S2 | c.827-1G>C p.X276_splice | Splice Site (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2
- EP300 | c.4009_4020del p.P1337_K1340del | In Frame Del (DEL) | VAF 171/613 reads (28%) | called by mutect2, pindel, varscan2
- EPHA8 | c.2914_2915del p.A972Pfs*57 | Frame Shift Del (DEL) | VAF 96/251 reads (38%) | called by pindel, varscan2
- EPPK1 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EXT2 | c.1660G>C p.E554Q (on ENST00000343631; = p.E587Q on NM_000401.3) | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- FAM207A | c.364A>T p.I122L | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FBN3 | c.383del p.G128Afs*64 | Frame Shift Del (DEL) | VAF 70/247 reads (28%) | called by mutect2, pindel, varscan2
- FOXP3 | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- GALNS | c.120C>G p.D40E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GALNT16 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GBA | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 192/734 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GDPD4 | c.1541-1G>A p.X514_splice | Splice Site (SNP) | VAF 47/344 reads (14%) | called by muse, mutect2, varscan2
- GMNC | c.428T>A p.F143Y | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2
- GON4L | c.2686T>A p.C896S | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GP5 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 38/418 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2
- HNRNPA1L2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- HSPA4 | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HTR3A | c.804dup p.N269Qfs*25 | Frame Shift Ins (INS) | VAF 113/425 reads (27%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 54/208 reads (26%) | called by muse, mutect2, varscan2
- INPP5D | c.2513C>A p.T838N (on ENST00000445964 / NM_001017915.3; = p.T837N on NM_005541.5) | Missense Mutation (SNP) | VAF 105/191 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA11 | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KDR | c.1955G>T p.R652I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LINC00634 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 104/379 reads (27%) | PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRP2 | c.11294G>T p.R3765L | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- LRP4 | c.4030G>C p.D1344H | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LYPD4 | c.83del p.L28Cfs*22 | Frame Shift Del (DEL) | VAF 33/125 reads (26%) | called by mutect2, pindel, varscan2
- MEIS2 | c.454C>G p.Q152E (on ENST00000561208 / NM_170675.5; = p.Q139E on NM_002399.3) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MFSD9 | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MSL3 | c.802A>C p.T268P (on ENST00000312196 / NM_078629.4; = p.T102P on NM_006800.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTMR3 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MXRA8 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MYRF | c.1734G>C p.K578N (on ENST00000278836 / NM_001127392.3; = p.K569N on NM_013279.4) | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- NAV2 | c.2103-1G>T p.X701_splice (on ENST00000396087 / NM_001244963.2; = p.X678_splice on NM_145117.5) | Splice Site (SNP) | VAF 26/68 reads (38%) | called by muse, varscan2
- NHS | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 223/323 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- NLRP4 | c.2157C>A p.N719K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NOBOX | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NRG1 | c.1736A>G p.D579G (on ENST00000405005 / NM_013964.5; = p.D584G on NM_013956.5) | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OAS2 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR13C3 | c.1022_1023insA p.N342Efs*? | Frame Shift Ins (INS) | VAF 34/60 reads (57%) | called by mutect2, pindel*, varscan2
- OR8B3 | c.619A>T p.I207F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); called by muse, mutect2
- OTOA | c.3021G>C p.K1007N (on ENST00000286149; = p.K993N on NM_144672.4) | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP2 | c.19_43del p.R7Efs*3 | Frame Shift Del (DEL) | VAF 7/97 reads (7%) | called by mutect2, pindel
- PCDH11Y | c.1975C>A p.P659T (on ENST00000400457 / NM_032973.2; = p.P648T on NM_032971.3) | Missense Mutation (SNP) | VAF 107/214 reads (50%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDH11Y | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 110/195 reads (56%) | called by muse, mutect2, varscan2
- PCDHA11 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 283/567 reads (50%) | called by muse, mutect2, varscan2
- PLK1 | c.1608+1G>A p.X536_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- POLR2B | c.1706T>A p.V569D | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R12C | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 19/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PTGIR | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PTRH1 | c.417-3A>T | Splice Region (SNP) | VAF 45/373 reads (12%) | called by muse, mutect2, varscan2
- PTTG2 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- RBM39 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- RDX | c.1517T>A p.M506K | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RFX4 | c.2120C>G p.T707R (on ENST00000392842 / NM_213594.3; = p.T613R on NM_032491.6) | Missense Mutation (SNP) | VAF 122/225 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SEC24B | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC63 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- SLC27A5 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 56/194 reads (29%) | called by muse, mutect2, varscan2
- SLC35G4 | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 171/641 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, varscan2
- SLC5A2 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPARC | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SPATA17 | c.723+2T>C p.X241_splice | Splice Site (SNP) | VAF 75/186 reads (40%) | called by muse, mutect2
- SUPT20HL1 | c.1449A>T p.Q483H | Missense Mutation (SNP) | VAF 298/473 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SVEP1 | c.5650G>C p.E1884Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- TAOK3 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D31 | c.3177A>T p.Q1059H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TEK | c.2834C>G p.A945G | Missense Mutation (SNP) | VAF 66/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TGFBRAP1 | c.2356G>T p.V786L | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.091); called by muse, mutect2
- THAP12 | c.2241G>T p.K747N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN1 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- TNR | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TOPBP1 | c.4408G>T p.A1470S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, varscan2
- TRBC2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.162); called by muse, mutect2
- TTLL13P | c.1795C>A p.L599I | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- TTYH2 | c.634A>G p.R212G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TYK2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP20 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 140/260 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VLDLR | c.417T>A p.D139E | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WHAMM | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ZNF274 | c.1267G>A p.D423N (on ENST00000610905; = p.D318N on NM_016324.3) | Missense Mutation (SNP) | VAF 64/774 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.539); called by muse, mutect2
- ZNF33B | c.1674T>G p.C558W | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF398 | c.1638G>T p.K546N (on ENST00000475153 / NM_170686.3; = p.K375N on NM_020781.4) | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF398 | c.1639A>T p.S547C (on ENST00000475153 / NM_170686.3; = p.S376C on NM_020781.4) | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF462 | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 70/594 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF618 | c.1543_1554del p.L515_F518del (on ENST00000374126 / NM_001318042.2; = p.L422_F425del on NM_133374.2) | In Frame Del (DEL) | VAF 67/181 reads (37%) | called by mutect2, pindel, varscan2
- ZNF671 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF813 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AARS2 | c.990A>C p.T330= | Silent (SNP) | VAF 55/248 reads (22%) | catalogued as COSV55116313, COSV99771436; called by muse, mutect2, varscan2
- ACBD7 | c.87C>T p.L29= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs11598719, COSV62252598; called by muse, mutect2, varscan2
- ACTC1 | c.942T>C p.R314= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs778914066, COSV51760107; called by muse, mutect2, varscan2
- ADGRA2 | c.3882G>A p.S1294= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1258510773; called by muse, mutect2, varscan2
- ADNP2 | c.2892C>A p.V964= | Silent (SNP) | VAF 71/166 reads (43%) | catalogued as COSV51540572; called by muse, mutect2, varscan2
- AK9 | c.3936G>A p.L1312= | Silent (SNP) | VAF 74/186 reads (40%) | catalogued as COSV69852405; called by muse, mutect2, varscan2
- ANGPT4 | c.1431C>T p.D477= | Silent (SNP) | VAF 42/358 reads (12%) | catalogued as rs750544749, COSV67922216; called by muse, mutect2, varscan2
- ANKRD30B | c.63C>T p.F21= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV62823369; called by muse, varscan2
- APLP1 | c.894T>C p.F298= | Silent (SNP) | VAF 83/250 reads (33%) | catalogued as COSV55705144; called by muse, mutect2, varscan2
- APOB | c.133C>A p.R45= | Silent (SNP) | VAF 104/592 reads (18%) | catalogued as COSV51923448, COSV51943073; called by muse, mutect2, varscan2
- ARL4A | c.453A>G p.L151= | Silent (SNP) | VAF 66/393 reads (17%) | called by muse, mutect2, varscan2
- ASB15 | c.297C>G p.S99= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV51927555; called by muse, mutect2, varscan2
- ASCC2 | c.264G>A p.Q88= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57074968; called by muse, mutect2, varscan2
- ATP2C1 | c.792C>G p.L264= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as COSV100147081, COSV60759031; called by muse, mutect2, varscan2
- BCKDHB | c.729T>A p.L243= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- BCL6 | c.834T>G p.A278= | Silent (SNP) | VAF 20/425 reads (5%) | called by muse, mutect2
- BRINP1 | c.2025G>A p.Q675= | Silent (SNP) | VAF 138/253 reads (55%) | catalogued as COSV56305934; called by muse, mutect2, varscan2
- C19orf81 | c.486C>T p.I162= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as rs563701623; called by muse, mutect2, varscan2
- C6orf132 | c.894C>T p.F298= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1472069562, COSV59374881; called by muse, mutect2, varscan2
- CABIN1 | c.4998G>A p.E1666= | Silent (SNP) | VAF 48/367 reads (13%) | catalogued as rs1284328989; called by muse, mutect2, varscan2
- CALCB | c.276G>T p.R92= | Silent (SNP) | VAF 56/245 reads (23%) | catalogued as COSV60834636; called by muse, mutect2, varscan2
- CCDC136 | c.2562G>A p.V854= | Silent (SNP) | VAF 141/327 reads (43%) | catalogued as COSV52799777; called by muse, mutect2, varscan2
- CCDC168 | c.8460T>A p.G2820= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV70555548; called by muse, mutect2, varscan2
- CCDC54 | c.918C>T p.I306= | Silent (SNP) | VAF 99/200 reads (50%) | catalogued as COSV53759231, COSV99660260; called by muse, mutect2, varscan2
- CDH16 | c.1032C>T p.S344= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- CEP192 | c.6096A>T p.V2032= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV58067311; called by muse, mutect2, varscan2
- CLTC | c.3381T>G p.S1127= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV52249624; called by muse, mutect2, varscan2
- CNTN5 | c.1881G>A p.R627= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV54330983; called by muse, mutect2, varscan2
- CNTN5 | c.2643T>C p.D881= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1089C>T p.I363= | Silent (SNP) | VAF 100/258 reads (39%) | catalogued as COSV52852230, COSV52852235; called by muse, varscan2
- CNTNAP5 | c.1569G>A p.K523= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV70483900, COSV70517922; called by muse, mutect2, varscan2
- COG5 | c.1305A>T p.P435= | Silent (SNP) | VAF 86/194 reads (44%) | catalogued as COSV51756987; called by muse, mutect2, varscan2
- CSMD1 | c.3750C>T p.A1250= (on ENST00000520002; = p.A1249= on NM_033225.6) | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs746940401, COSV100150563; called by muse, mutect2, varscan2
- CYLC2 | c.102C>A p.A34= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- DAAM2 | c.798G>T p.R266= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV51357231; called by muse, mutect2, varscan2
- DAGLB | c.165C>G p.L55= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as rs906879848; called by muse, mutect2, varscan2
- DDX42 | c.450C>T p.D150= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV63790657; called by muse, mutect2, varscan2
- DHX33 | c.699G>A p.T233= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs752914392, COSV56579920; called by muse, mutect2, varscan2
- DLGAP2 | c.1038C>T p.N346= | Silent (SNP) | VAF 107/356 reads (30%) | catalogued as COSV70101021; called by muse, mutect2, varscan2
- EFEMP1 | c.18C>T p.F6= | Silent (SNP) | VAF 225/611 reads (37%) | catalogued as rs182486751; called by muse, mutect2, varscan2
- EFNB3 | c.190C>A p.R64= | Silent (SNP) | VAF 91/174 reads (52%) | catalogued as rs17854240, COSV56833858; called by muse, mutect2, varscan2
- EGF | c.1143G>A p.T381= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1289793145; called by muse, varscan2
- EGFR | c.3231G>A p.L1077= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs367750834; called by muse, mutect2, varscan2
- ENPP1 | c.306C>A p.A102= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV62933778, COSV62934073; called by muse, mutect2, varscan2
- ESYT3 | c.786G>T p.P262= | Silent (SNP) | VAF 33/406 reads (8%) | catalogued as COSV56680255; called by muse, mutect2
- FAM135B | c.2113C>T p.L705= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV52738475; called by muse, mutect2, varscan2
- FASTK | c.1176C>G p.T392= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- FATE1 | c.495C>A p.I165= | Silent (SNP) | VAF 100/149 reads (67%) | catalogued as rs1457896176, COSV64848834; called by muse, mutect2, varscan2
- FBXL18 | c.1600C>A p.R534= | Silent (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- FBXO40 | c.1605C>A p.I535= | Silent (SNP) | VAF 126/715 reads (18%) | catalogued as COSV57525655; called by muse, mutect2, varscan2
- FCHO1 | c.2514G>A p.P838= | Silent (SNP) | VAF 65/223 reads (29%) | catalogued as rs754360221; called by muse, mutect2, varscan2
- FGA | c.1818G>A p.E606= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as rs375428976; called by muse, mutect2, varscan2
- FLG | c.2349A>T p.S783= | Silent (SNP) | VAF 233/696 reads (33%) | called by muse, mutect2, varscan2
- FOXC2 | c.1077G>T p.S359= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as rs779738916; called by muse, mutect2, varscan2
- GLYATL2 | c.699A>G p.R233= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- GPRIN3 | c.474A>G p.S158= | Silent (SNP) | VAF 106/259 reads (41%) | catalogued as COSV60885535; called by muse, mutect2, varscan2
- GRAMD1B | c.246T>C p.S82= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV59200663; called by muse, mutect2, varscan2
- GREM2 | c.57G>T p.A19= | Silent (SNP) | VAF 53/173 reads (31%) | catalogued as COSV100548036, COSV58953880; called by muse, mutect2, varscan2
- GSG1 | c.675C>T p.V225= (on ENST00000651961 / NM_001080555.4; = p.L231F on NM_031289.5) | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as COSV52195820; called by muse, mutect2, varscan2
- IGF1R | c.1692C>T p.P564= | Silent (SNP) | VAF 92/286 reads (32%) | catalogued as rs9282723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as rs376111067; called by muse, mutect2, varscan2
- IGLV5-52 | c.204C>A p.L68= | Silent (SNP) | VAF 106/618 reads (17%) | called by muse, mutect2, varscan2
- ITGA4 | c.2772C>A p.S924= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV67898016; called by muse, mutect2, varscan2
- KCNJ11 | c.282C>T p.A94= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as COSV60595056; called by muse, mutect2, varscan2
- KIAA0825 | c.702T>C p.D234= | Silent (SNP) | VAF 81/166 reads (49%) | catalogued as COSV56955634; called by muse, mutect2, varscan2
- KIF13B | c.5073C>T p.S1691= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as COSV68094424; called by muse, mutect2, varscan2
- KNTC1 | c.4395C>T p.F1465= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as rs773362150; called by muse, mutect2, varscan2
- LAMA2 | c.3528T>C p.S1176= | Silent (SNP) | VAF 69/372 reads (19%) | catalogued as rs1462835620; called by muse, mutect2, varscan2
- LIM2 | c.273C>T p.T91= (on ENST00000596399 / NM_001161748.2; = p.T133= on NM_030657.4) | Silent (SNP) | VAF 201/656 reads (31%) | catalogued as rs748687283; called by muse, mutect2, varscan2
- MAP1A | c.3624C>G p.T1208= | Silent (SNP) | VAF 65/325 reads (20%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1158C>G p.L386= | Silent (SNP) | VAF 56/181 reads (31%) | called by muse, mutect2, varscan2
- MAU2 | c.918G>A p.L306= | Silent (SNP) | VAF 141/469 reads (30%) | catalogued as COSV53236699; called by muse, mutect2, varscan2
- MICALL1 | c.1188C>T p.S396= | Silent (SNP) | VAF 87/597 reads (15%) | catalogued as rs1403507760; called by muse, mutect2, varscan2
- MME | c.291T>C p.I97= | Silent (SNP) | VAF 66/363 reads (18%) | called by muse, mutect2, varscan2
- MTDH | c.246G>A p.R82= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV60345319; called by muse, mutect2, varscan2
- MUC16 | c.16014G>A p.L5338= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV67478659; called by muse, mutect2, varscan2
- MUC5B | c.1146C>T p.L382= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as rs569619858, COSV101500229, COSV71593995; called by muse, mutect2, varscan2
- MUCL3 | c.1272C>G p.L424= (on ENST00000304311; = p.L1300= on NM_080870.4) | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100424489; called by muse, mutect2, varscan2
- MUCL3 | c.1500C>T p.V500= (on ENST00000304311; = p.V1376= on NM_080870.4) | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- MYADML2 | c.753C>T p.V251= | Silent (SNP) | VAF 152/400 reads (38%) | catalogued as rs1261812325, COSV57999584; called by muse, mutect2, varscan2
- MYLK2 | c.1047C>A p.I349= | Silent (SNP) | VAF 205/645 reads (32%) | catalogued as COSV65658879, COSV65659488; called by muse, mutect2, varscan2
- NCOA1 | c.1689G>A p.Q563= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- NID2 | c.3228C>A p.S1076= | Silent (SNP) | VAF 92/175 reads (53%) | catalogued as COSV53499395; called by muse, mutect2, varscan2
- NLRP10 | c.463C>T p.L155= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV60781176; called by muse, mutect2, varscan2
- NRXN3 | c.633G>A p.A211= (on ENST00000557594 / NM_001272020.2; = p.A843= on NM_004796.6) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs527486862, COSV55365449; called by muse, mutect2, varscan2
- NXPH2 | c.372C>T p.V124= | Silent (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- OR10S1 | c.717G>T p.V239= | Silent (SNP) | VAF 12/285 reads (4%) | catalogued as COSV73343026; called by muse, mutect2
- OR5B17 | c.168C>A p.P56= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100641920; called by muse, mutect2, varscan2
- OR9Q2 | c.507T>C p.C169= | Silent (SNP) | VAF 62/382 reads (16%) | catalogued as COSV61112264; called by muse, mutect2, varscan2
- OSBP2 | c.1698G>A p.K566= | Silent (SNP) | VAF 182/571 reads (32%) | catalogued as rs1163326015, COSV60245302; called by muse, mutect2, varscan2
- PANX1 | c.147C>A p.L49= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- PARP12 | c.1023T>G p.S341= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs781048651; called by muse, mutect2, varscan2
- PDILT | c.1638C>T p.S546= | Silent (SNP) | VAF 106/209 reads (51%) | catalogued as rs1376550063, COSV56703236; called by muse, mutect2, varscan2
- PHOX2B | c.462C>T p.R154= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- PIK3C2G | c.225G>A p.G75= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV99851277; called by muse, mutect2, varscan2
- PLEC | c.4467G>A p.E1489= (on ENST00000322810 / NM_201380.4; = p.E1379= on NM_000445.5) | Silent (SNP) | VAF 132/365 reads (36%) | catalogued as rs781942137, COSV59659870; called by muse, mutect2, varscan2
- PLSCR1 | c.438T>A p.T146= | Silent (SNP) | VAF 139/597 reads (23%) | catalogued as COSV61013237; called by muse, mutect2, varscan2
- PRSS57 | c.162G>C p.G54= | Silent (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- RASAL3 | c.2733C>T p.L911= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1252888544, COSV54609585, COSV54609638; called by muse, mutect2, varscan2
- RING1 | c.741A>T p.P247= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- RNF150 | c.771C>T p.S257= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60794758; called by muse, mutect2, varscan2
- ROPN1L | c.348A>G p.Q116= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as rs370843883; called by muse, mutect2, varscan2
- RUVBL1 | c.1311C>T p.F437= | Silent (SNP) | VAF 107/501 reads (21%) | catalogued as COSV59476459; called by muse, mutect2, varscan2
- SAMD9 | c.4659C>T p.I1553= | Silent (SNP) | VAF 39/429 reads (9%) | catalogued as COSV66076571; called by muse, mutect2
- SASH1 | c.114C>G p.S38= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- SCAP | c.150A>T p.P50= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV55563435; called by muse, mutect2, varscan2
- SCN7A | c.2403C>A p.T801= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV69273021; called by muse, mutect2, varscan2
- SDK1 | c.5385G>T p.G1795= | Silent (SNP) | VAF 73/139 reads (53%) | catalogued as rs376434386; called by muse, mutect2, varscan2
- SLC17A4 | c.1302C>T p.V434= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55080293; called by muse, mutect2, varscan2
- SLC43A3 | c.1221G>A p.G407= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs1284125919; called by muse, varscan2
- SLC6A3 | c.882C>A p.I294= | Silent (SNP) | VAF 258/787 reads (33%) | catalogued as COSV54366513; called by muse, mutect2, varscan2
- SMCHD1 | c.69C>T p.V23= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55261954; called by mutect2, varscan2
- SNX32 | c.877C>T p.L293= | Silent (SNP) | VAF 74/262 reads (28%) | catalogued as COSV100362568, COSV57450040; called by muse, mutect2, varscan2
- SPATA16 | c.1203A>C p.S401= | Silent (SNP) | VAF 22/437 reads (5%) | called by muse, mutect2
- SPEF2 | c.1593A>T p.I531= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV61550710; called by muse, mutect2, varscan2
- TDRD10 | c.366G>A p.P122= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs907639076, COSV63813057; called by muse, mutect2, varscan2
- TEX2 | c.1137G>A p.E379= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as COSV51983216; called by muse, mutect2, varscan2
- THSD7A | c.4329C>T p.V1443= | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as COSV70268191; called by muse, mutect2, varscan2
- TM7SF3 | c.48C>T p.H16= | Silent (SNP) | VAF 252/403 reads (63%) | catalogued as COSV58003142; called by muse, mutect2, varscan2
- TRIM42 | c.1887C>T p.D629= | Silent (SNP) | VAF 23/343 reads (7%) | catalogued as rs1190528770; called by muse, mutect2
- TTN | c.5175G>A p.R1725= (on ENST00000591111; = p.R1679= on NM_003319.4) | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV60183480; called by muse, mutect2, varscan2
- UBQLN3 | c.1575G>A p.R525= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- ZDHHC19 | c.708C>T p.Y236= | Silent (SNP) | VAF 77/430 reads (18%) | catalogued as COSV56349309; called by muse, mutect2, varscan2
- ZNF692 | c.888G>C p.G296= | Silent (SNP) | VAF 47/298 reads (16%) | called by muse, mutect2, varscan2
- ZNF865 | c.2631A>T p.R877= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV57596410; called by muse, mutect2, varscan2
- AC004837.1 | chr7:39609667 C>T | 5'Flank (SNP) | VAF 52/312 reads (17%) | called by muse, mutect2, varscan2
- AC027559.1 | n.407G>T | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- AC099654.5 | n.87A>T | RNA (SNP) | VAF 15/70 reads (21%) | catalogued as rs1361352340; called by muse, mutect2, varscan2
- ADAM10 | c.207-10185G>C | Intron (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- AFP | c.*96G>A | 3'UTR (SNP) | VAF 36/54 reads (67%) | catalogued as COSV56924990; called by muse, mutect2, varscan2
- ALG11 | c.*80C>T | 3'UTR (SNP) | VAF 66/340 reads (19%) | catalogued as rs749248865; called by muse, mutect2, varscan2
- AMPH | c.1182+601G>T | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621880 C>T | 5'Flank (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1791C>A | RNA (SNP) | VAF 26/68 reads (38%) | called by muse, varscan2
- ARMC2 | c.671+3634A>G | Intron (SNP) | VAF 29/142 reads (20%) | catalogued as rs1468260573; called by muse, mutect2, varscan2
- ASAH1 | c.833+12C>T | Intron (SNP) | VAF 113/226 reads (50%) | catalogued as rs893380370, COSV50505490; called by muse, mutect2, varscan2
- AUP1 | c.-26G>A | 5'UTR (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2984G>A | Intron (SNP) | VAF 15/289 reads (5%) | catalogued as COSV53800822; called by muse, mutect2
- CCDC112 | chr5:115296432 G>C | 5'Flank (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- CFAP47 | c.5536-500dup | Intron (INS) | VAF 40/73 reads (55%) | catalogued as rs752230500; called by mutect2, varscan2
- CLCN6 | c.2529+126A>G | Intron (SNP) | VAF 158/309 reads (51%) | called by muse, mutect2, varscan2
- COL4A3 | c.2656+10T>A | Intron (SNP) | VAF 93/209 reads (44%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*1251G>C | 3'UTR (SNP) | VAF 44/121 reads (36%) | catalogued as COSV100381772; called by muse, mutect2, varscan2
- CST9LP1 | n.385G>C | RNA (SNP) | VAF 53/232 reads (23%) | called by muse, mutect2, varscan2
- CYP2S1 | c.*63G>A | 3'UTR (SNP) | VAF 60/409 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.7605G>A | RNA (SNP) | VAF 10/27 reads (37%) | catalogued as rs181609649, COSV100601609, COSV61768891; called by muse, mutect2, varscan2
- DCHS2 | n.5200G>T | RNA (SNP) | VAF 4/24 reads (17%) | catalogued as rs577146168, COSV61775385; called by mutect2, varscan2
- EFCAB12 | c.-18C>T | 5'UTR (SNP) | VAF 77/240 reads (32%) | catalogued as rs779067964; called by muse, mutect2, varscan2
- ELAPOR2 | c.*57A>G | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2
- FAM161A | c.*953A>T | 3'UTR (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643607 C>T | 5'Flank (SNP) | VAF 78/247 reads (32%) | catalogued as rs1016857182; called by mutect2, varscan2
- GPI | chr19:34365008 G>A | 5'Flank (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- GUSBP10 | n.600G>T | RNA (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- HGF | c.482+31C>T | Intron (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- JAZF1 | c.116-256dup | Intron (INS) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- LILRB4 | chr19:54662938 C>A | 5'Flank (SNP) | VAF 42/118 reads (36%) | called by muse, mutect2, varscan2
- LINC02691 | n.1445C>T | RNA (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- LINC02874 | n.509C>T | RNA (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- MFSD4B | c.*496G>C | 3'UTR (SNP) | VAF 46/248 reads (19%) | called by muse, mutect2, varscan2
- MIR890 | n.35A>T | RNA (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- MIR890 | n.34T>A | RNA (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92468G>A | Intron (SNP) | VAF 36/109 reads (33%) | catalogued as rs989699322; called by muse, mutect2, varscan2
- MTND6P20 | chr8:46841105 G>C | 3'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- NBEAP1 | n.37G>T | RNA (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- NPL | c.*19G>A | 3'UTR (SNP) | VAF 69/239 reads (29%) | called by muse, mutect2, varscan2
- NSRP1 | c.20+256C>G | Intron (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- OR2W5 | n.1129C>T | RNA (SNP) | VAF 105/363 reads (29%) | catalogued as rs763007594; called by muse, mutect2, varscan2
- PCDH11Y | c.3129+43dup | Intron (INS) | VAF 90/152 reads (59%) | called by mutect2, varscan2
- PDE4D | c.809-10C>G | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs1379108278; called by muse, mutect2, varscan2
- PLCD1 | c.1287+28G>A | Intron (SNP) | VAF 86/167 reads (51%) | called by muse, mutect2, varscan2
- PMM2 | c.178+390A>G | Intron (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75780338 A>G | 5'Flank (SNP) | VAF 149/670 reads (22%) | catalogued as rs767080613; called by muse, mutect2, varscan2
- SAMSN1 | c.-17G>C | 5'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- SLC39A3 | chr19:2732283 G>C | 3'Flank (SNP) | VAF 53/443 reads (12%) | catalogued as COSV54119152; called by muse, mutect2, varscan2
- SLC39A7 | chr6:33200756 C>A | 5'Flank (SNP) | VAF 75/289 reads (26%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1171+13G>A | Intron (SNP) | VAF 30/618 reads (5%) | called by muse, mutect2
- SLCO1C1 | c.1916+10C>G | Intron (SNP) | VAF 16/414 reads (4%) | catalogued as COSV99860139; called by muse, mutect2
- SPATA31D5P | n.492G>T | RNA (SNP) | VAF 41/275 reads (15%) | catalogued as rs753945846; called by muse, mutect2, varscan2
- STK26 | c.-147G>T | 5'UTR (SNP) | VAF 104/150 reads (69%) | called by muse, mutect2, varscan2
- TANK | c.-49-18280T>A | Intron (SNP) | VAF 104/325 reads (32%) | called by muse, mutect2, varscan2
- TBCD | c.2991+111A>G | Intron (SNP) | VAF 88/304 reads (29%) | catalogued as rs746785278; called by muse, mutect2, varscan2
- TINAG | c.624+232T>G | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- TIPIN | c.475+1744T>G | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- TMEM135 | c.*1431G>T | 3'UTR (SNP) | VAF 59/143 reads (41%) | catalogued as rs1388297574; called by muse, mutect2, varscan2
- UCK2 | c.-38C>G | 5'UTR (SNP) | VAF 15/38 reads (39%) | catalogued as rs761644178; called by muse, mutect2, varscan2
- WT1 | chr11:32438563 C>T | 5'Flank (SNP) | VAF 31/322 reads (10%) | called by muse, mutect2
- Z98752.3 | c.201+7328A>T | Intron (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- ZNF135 | c.33+10T>A | Intron (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- ZNF268 | c.*6263G>A | 3'UTR (SNP) | VAF 92/140 reads (66%) | called by muse, varscan2
